Somatic mutation profile of tumor specimen TCGA-06-5412-01A (aliquot TCGA-06-5412-01A-01D-1696-08) from TCGA case TCGA-06-5412, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 78.7 years (28,762 days).
Specimen TCGA-06-5412-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b65946e4-f4a8-4c8a-b6d3-a78775d2d1a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-5412-10A (Blood Derived Normal), aliquot TCGA-06-5412-10A-01D-1696-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c231c1a3-e5e8-4aed-93db-edeb2d563aa3

The open-access MAF lists 54 somatic variants for this specimen: 40 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 33, Silent 14, Nonsense Mutation 4, Frame Shift Del 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.1529A>T p.Q510L | Missense Mutation (SNP) | VAF 27/245 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as CM043070, CM052358, COSV61008620; called by muse, mutect2, varscan2
- AHSA1 | c.488T>A p.M163K | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53632425; called by muse, varscan2
- BTNL3 | c.1076G>A p.R359Q | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs199970076, COSV61565155; called by muse, mutect2, varscan2
- CCL24 | c.151C>G p.Q51E | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV56116359; called by muse, mutect2
- CDHR3 | c.1796C>T p.P599L | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV58418732; called by muse, mutect2, varscan2
- CREB3L3 | c.686C>T p.T229I | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV50218864; called by muse, mutect2
- CYRIB | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.166); catalogued as rs200940349, COSV67831088; called by muse, mutect2
- DIAPH3 | c.336C>A p.N112K | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.084); catalogued as COSV57373159; called by muse, mutect2, varscan2
- DPP10 | c.2036A>T p.D679V | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59694106; called by muse, mutect2, varscan2
- ENPP2 | c.766G>A p.G256R | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV50020457; called by muse, mutect2, varscan2
- GLIS1 | c.760C>T p.R254* | Nonsense Mutation (SNP) | VAF 7/46 reads (15%) | catalogued as rs781071820, COSV56551182; called by muse, varscan2
- GNRHR | c.808G>A p.V270I | Missense Mutation (SNP) | VAF 36/236 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.116); catalogued as COSV56934037; called by muse, mutect2, varscan2
- HAS2 | c.1556A>G p.Y519C | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1372480161, COSV58265084; called by muse, mutect2, varscan2
- HGSNAT | c.1423G>C p.G475R | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52817652; called by muse, mutect2
- ITGA10 | c.775C>T p.Q259* | Nonsense Mutation (SNP) | VAF 31/209 reads (15%) | catalogued as COSV65197982; called by muse, mutect2, varscan2
- MAP3K9 | c.1793C>T p.T598M | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs572761925, COSV67121026; called by muse, mutect2, varscan2
- MECOM | c.911C>T p.P304L (on ENST00000468789 / NM_001105078.4; = p.P492L on NM_004991.4) | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52967739; called by muse, mutect2, varscan2
- NAALADL2 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV70296000; called by muse, mutect2, varscan2
- NF1 | c.4977_4980del p.K1661Gfs*36 (on ENST00000358273 / NM_001042492.3; = p.K1640Gfs*36 on NM_000267.3) | Frame Shift Del (DEL) | VAF 35/174 reads (20%) | catalogued as rs1085307459; called by mutect2, pindel, varscan2
- NOP56 | c.68A>T p.E23V | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV61390502; called by muse, mutect2, varscan2
- NPC1 | c.2527G>A p.V843M | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.231); catalogued as COSV52580291; called by muse, mutect2, varscan2
- PCDHGB1 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); catalogued as COSV53959666; called by muse, mutect2
- PITX2 | c.775A>G p.T259A (on ENST00000354925 / NM_001204397.1; = p.T266A on NM_000325.6) | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV60741387; called by muse, mutect2, varscan2
- PLEKHM3 | c.1459C>T p.R487C | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200329503, COSV66817212; called by muse, mutect2, varscan2
- PLXNA3 | c.755C>A p.T252K | Missense Mutation (SNP) | VAF 21/195 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.246); catalogued as COSV63754571; called by muse, mutect2, varscan2
- PPP4R1 | c.1246C>T p.Q416* (on ENST00000400556 / NM_001042388.3; = p.Q399* on NM_005134.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 19/86 reads (22%) | catalogued as COSV53282382; called by muse, mutect2, varscan2
- RHBDL1 | c.592G>A p.V198M (on ENST00000219551 / NM_001318733.2; = p.V133M on NM_001278720.2) | Missense Mutation (SNP) | VAF 9/144 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.483); catalogued as rs1255829696, COSV53485078; called by muse, mutect2
- ROS1 | c.3788C>A p.P1263H | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.371); catalogued as COSV63856561; called by muse, mutect2, varscan2
- RPS6KA5 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as rs534048620, COSV56223160; called by muse, mutect2, varscan2
- RXRA | c.485C>T p.T162M | Missense Mutation (SNP) | VAF 26/247 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62683390; called by muse, varscan2
- SCAF4 | c.416G>A p.S139N | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.244); catalogued as rs779499627, COSV54588976; called by muse, mutect2
- SENP8 | c.127_130del p.Q43Ffs*45 | Frame Shift Del (DEL) | VAF 16/157 reads (10%) | catalogued as rs772976152; called by pindel, varscan2
- SOX7 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.103); catalogued as rs1222703120, COSV58731143; called by muse, mutect2
- TEX11 | c.1090C>T p.R364C (on ENST00000344304; = p.R349C on NM_031276.3) | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs773463882, COSV60229606; called by muse, mutect2, varscan2
- TP53RK | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 18/139 reads (13%) | catalogued as COSV64509025; called by muse, mutect2, varscan2
- TRAPPC8 | c.1358A>C p.D453A | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV51973630; called by muse, mutect2, varscan2
- VCX3B | c.102G>C p.K34N | Missense Mutation (SNP) | VAF 18/284 reads (6%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.895); catalogued as COSV66842918; called by muse, mutect2
- ZIC4 | c.544G>C p.G182R | Missense Mutation (SNP) | VAF 41/319 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.964); catalogued as COSV67171167, COSV67172543; called by muse, mutect2, varscan2
- ZNF37A | c.1434G>T p.Q478H | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as COSV100697250; called by muse, varscan2
- PTEN | c.982del p.A328Qfs*16 | Frame Shift Del (DEL) | VAF 11/66 reads (17%) | called by mutect2, pindel, varscan2
- ADGRG1 | c.732C>T p.A244= | Silent (SNP) | VAF 12/106 reads (11%) | catalogued as rs374209597; called by muse, mutect2
- CRTC2 | c.1236C>T p.G412= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs201148360; called by muse, mutect2, varscan2
- DDX56 | c.819G>T p.R273= | Silent (SNP) | VAF 16/140 reads (11%) | catalogued as COSV51837012; called by muse, mutect2, varscan2
- EBF1 | c.1224C>T p.A408= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as rs1046508895, COSV100566135, COSV58182589; called by muse, mutect2, varscan2
- FHL1 | c.753C>T p.H251= | Silent (SNP) | VAF 7/103 reads (7%) | catalogued as COSV61781668; called by muse, mutect2
- GTF2IRD2 | c.1452G>A p.E484= | Silent (SNP) | VAF 26/206 reads (13%) | catalogued as COSV63100508; called by muse, mutect2, varscan2
- HOXD10 | c.165G>A p.P55= | Silent (SNP) | VAF 9/129 reads (7%) | catalogued as rs1438215691, COSV50898406; called by muse, mutect2
- IGF2BP1 | c.1155G>A p.P385= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as rs369774252; called by muse, mutect2
- KRT35 | c.159A>T p.S53= | Silent (SNP) | VAF 15/91 reads (16%) | catalogued as COSV55843677; called by muse, mutect2, varscan2
- OR2G6 | c.105C>T p.Y35= | Silent (SNP) | VAF 22/159 reads (14%) | catalogued as rs772692766, COSV58574983; called by muse, mutect2, varscan2
- PADI4 | c.1806C>T p.F602= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs373192530; called by mutect2, varscan2
- RBM44 | c.864G>A p.S288= (on ENST00000611254; = p.S922= on NM_001080504.2) | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as rs376575329; called by muse, mutect2, varscan2
- SLITRK2 | c.1059T>C p.N353= | Silent (SNP) | VAF 15/93 reads (16%) | catalogued as COSV59426705; called by muse, mutect2, varscan2
- USP9X | c.5604G>A p.V1868= | Silent (SNP) | VAF 12/154 reads (8%) | catalogued as rs753567750, COSV61071253; called by muse, mutect2
